Somatic mutation profile of tumor specimen ALCH-B1T8-TTP1-A (aliquot ALCH-B1T8-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1T8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.9 years (28,466 days).
Specimen ALCH-B1T8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e52d9461-0273-4fc3-8eca-5304ce954e23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1T8-NB1-A (Blood Derived Normal), aliquot ALCH-B1T8-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/504e50f9-920f-46d1-8354-95306153916b

The open-access MAF lists 67 somatic variants for this specimen: 54 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 7, Frame Shift Del 6, Intron 3, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 102/502 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 19/319 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 16/165 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AXL | c.2500C>T p.P834S (on ENST00000301178 / NM_021913.5; = p.P825S on NM_001699.6) | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as rs867040136; called by muse, mutect2
- CHRNA7 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200196560; called by muse, mutect2
- CSMD1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339881270; called by muse, mutect2, varscan2
- FBXO41 | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV54586466; called by muse, mutect2, varscan2
- KLHL6 | c.1719C>G p.I573M | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV58067029; called by muse, mutect2, varscan2
- MACF1 | c.14879G>A p.R4960H (on ENST00000372915; = p.R2893H on NM_012090.5) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as rs140695276; called by muse, mutect2, varscan2
- MACF1 | c.15001G>A p.E5001K (on ENST00000372915; = p.E2934K on NM_012090.5) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV57131285; called by muse, mutect2, varscan2
- MACF1 | c.15553G>C p.E5185Q (on ENST00000372915; = p.E3118Q on NM_012090.5) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99243273; called by muse, mutect2
- NLRP2 | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99672598; called by muse, mutect2
- NOS3 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs771167274; called by muse, mutect2, varscan2
- NUP205 | c.2827A>G p.I943V | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1215998608; called by muse, mutect2, varscan2
- OAS3 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201242016; called by muse, mutect2
- OR9G1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.734); catalogued as COSV56449043; called by muse, mutect2
- PPP1R17 | c.119T>A p.L40H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV59612164; called by muse, varscan2
- SLC36A1 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54653838; called by muse, mutect2, varscan2
- TGM7 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.922); catalogued as rs1172802923; called by muse, mutect2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 43/244 reads (18%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- TP53 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as rs922736614, COSV52696702, COSV52713465, COSV99391410; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBA1B | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60137252; called by muse, mutect2
- ADAM20 | c.448del p.V150Ffs*8 | Frame Shift Del (DEL) | VAF 33/168 reads (20%) | called by mutect2, pindel, varscan2
- AMZ1 | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKIB1 | c.2150T>C p.V717A | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CCDC149 | c.780_786dup p.S263Qfs*20 | Frame Shift Ins (INS) | VAF 24/154 reads (16%) | called by mutect2, varscan2
- CRYGS | c.384C>G p.H128Q | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DIDO1 | c.5275C>A p.H1759N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC1 | c.298T>C p.W100R | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EYS | c.6191G>C p.R2064T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- FANCD2OS | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- FOXF2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); called by muse, mutect2
- GSTM2 | c.104T>C p.M35T | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- HDAC4 | c.3058G>C p.V1020L | Missense Mutation (SNP) | VAF 64/537 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IGF2R | c.6350del p.F2117Sfs*11 | Frame Shift Del (DEL) | VAF 37/193 reads (19%) | called by mutect2, pindel, varscan2
- LDOC1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- LRIG1 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MACF1 | c.14581G>C p.E4861Q (on ENST00000372915; = p.E2794Q on NM_012090.5) | Missense Mutation (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- MACF1 | c.15739G>A p.D5247N (on ENST00000372915; = p.D3180N on NM_012090.5) | Missense Mutation (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- NAA25 | c.2231_2232del p.F744Yfs*2 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel
- NOS3 | c.1337C>G p.A446G | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NRP1 | c.796_814+19del p.X266_splice | Splice Site (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel
- NSD2 | c.2925G>C p.Q975H | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- OR14K1 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- P4HB | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2
- POLR2I | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2
- PPP1R15B | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, mutect2
- RBM10 | c.2145del p.K715Nfs*87 | Frame Shift Del (DEL) | VAF 69/350 reads (20%) | called by mutect2, pindel, varscan2
- SGCA | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.628); called by muse, mutect2
- THAP3 | c.700_703del p.G234Qfs*38 (on ENST00000054650 / NM_001195753.1; = p.G233Qfs*38 on NM_001195752.1) | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- TKTL1 | c.101A>G p.H34R | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTN | c.102660G>C p.E34220D (on ENST00000591111; = p.E26796D on NM_003319.4) | Missense Mutation (SNP) | VAF 22/191 reads (12%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC5C | c.1946A>C p.Y649S | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN16 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- CCDC185 | c.702G>A p.E234= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- HERC2 | c.7485G>A p.V2495= | Silent (SNP) | VAF 13/54 reads (24%) | called by mutect2, varscan2
- KAT6B | c.5526C>A p.S1842= | Silent (SNP) | VAF 34/618 reads (6%) | called by muse, mutect2
- MUC2 | c.2724C>T p.C908= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs536474040; called by muse, mutect2, varscan2
- PLCE1 | c.5544G>A p.K1848= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as rs373009697; called by muse, mutect2, varscan2
- SHLD1 | c.567A>G p.S189= | Silent (SNP) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- TRAF2 | c.429C>A p.V143= | Silent (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- ATP2A1 | c.1096-1810del | Intron (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel
- CSNK1E | c.885+557C>G | Intron (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- HOXA11 | chr7:27179779 G>T | 3'Flank (SNP) | VAF 17/577 reads (3%) | called by muse, mutect2
- JAZF1 | c.189-18024G>C | Intron (SNP) | VAF 22/178 reads (12%) | called by muse, varscan2
- LCOR | chr10:96828738 A>G | 5'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- TTN | c.-43G>T | 5'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
